Gene-level copy-number profile of tumor specimen TCGA-XE-AAND-01A from TCGA case TCGA-XE-AAND, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 39.6 years (14,452 days).
Specimen TCGA-XE-AAND-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e1e7a2d8-11f6-4305-9966-94552aaa8929.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-XE-AAND-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/42c6c0d3-feeb-432a-84ec-a2152da64392

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 36; copy number 2: 286; copy number 3: 5,134; copy number 4: 18,124; copy number 5: 14,809; copy number 6: 15,565; copy number 7: 3,059; copy number 8: 1,161; copy number 9: 713; copy number 10: 3; copy number 15: 4; copy number 20: 2; copy number 33: 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:112,967–186,136, 5 genes (within-gene range 0–3): AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 723 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–53,312, 3 genes, copy number 20–33: DDX11L1, FAM138A, OR4G4P.
- chr6:26,956,932–27,059,749, 3 genes, copy number 10 (within-gene range 5–10): LINC00240, AL133255.1, AL590062.1.
- chr21:13,038,160–44,106,552, 599 genes, copy number 9–15 (broad region; genes not listed).
- chr21:44,200,602–46,691,226, 118 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 36. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
